Gene-level copy-number profile of tumor specimen TCGA-55-7815-01A from TCGA case TCGA-55-7815, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 77.0 years (28,119 days).
Specimen TCGA-55-7815-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.4de2cbea-8ade-4f68-a18d-92f986984664.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-7815-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/95eaaa79-bb0e-494b-9328-7f73e032f106

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 442; copy number 2: 6,994; copy number 3: 22,190; copy number 4: 23,123; copy number 5: 3,469; copy number 6: 3,006; copy number 7: 276; copy number 8: 300; copy number 11: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-7815-01A-11D-2166-01): tumor purity 0.29, ploidy 3.48, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 13 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:18,080,869–19,108,183, 11 genes, copy number 11: RERGL, PIK3C2G, NDFIP1P1, AC092851.1, ZKSCAN7P1, PLCZ1, PSMC1P9, AC087242.1, CAPZA3, RPL7P6, MEF2BNBP1.
- chr12:19,147,074–19,176,589, 2 genes, copy number 11: AC092828.1, RN7SL459P.

Autosomal genes at a single copy (total copy number 1): 277. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
